Somatic mutation profile of tumor specimen MP2PRT-PATBBD-TMP1-A (aliquot MP2PRT-PATBBD-TMP1-A-1-0-D-A81O-36) from MP2PRT case MP2PRT-PATBBD, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: female; Primary diagnosis: Common precursor B ALL; Tissue or organ of origin: Bone marrow; Age at diagnosis: 2.7 years (984 days).
Specimen MP2PRT-PATBBD-TMP1-A: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 10f526d1-e358-4a9e-938f-9df8e8fa08a5.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PATBBD-NB1-A (Blood Derived Cancer - Peripheral Blood, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PATBBD-NB1-A-1-0-D-A81O-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/e34079ab-fc39-463a-8a4d-0c9b1aae81ff

The open-access MAF lists 4 somatic variants for this specimen: 4 protein-altering or splice-affecting.
By variant classification: Missense Mutation 4.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BCORL1 | c.3532G>A p.G1178R | Missense Mutation (SNP) | VAF 89/850 reads (10%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.786); catalogued as rs933989121, COSV54409964; called by muse, mutect2, varscan2
- ZNF728 | c.20G>A p.R7Q | Missense Mutation (SNP) | VAF 11/73 reads (15%) | SIFT tolerated (0.08); PolyPhen benign (0.007); catalogued as rs530488414, COSV74099329; called by muse, mutect2, varscan2
- DNAJC10 | c.1376G>A p.G459E | Missense Mutation (SNP) | VAF 84/211 reads (40%) | SIFT tolerated (0.32); PolyPhen probably damaging (0.946); called by muse, mutect2, varscan2
- IRS4 | c.3280G>T p.A1094S | Missense Mutation (SNP) | VAF 210/826 reads (25%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.09); called by muse, mutect2, varscan2
